Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4740, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4740-01A (Primary Tumor).

[page 1 of 6]
PATIENT HISTORY:

Malignant neoplasm.

PRE-OP DIAGNOSIS: Malignant neoplasm tonsil, malignant neoplasm mouth, [REDACTED]

POST-OP DIAGNOSIS: Same.

PROCEDURE: Dissection neck, free flap.

FINAL DIAGNOSIS:

PART 1: SOFT PALATE MARGIN, BIOPSY -
NO TUMOR SEEN.

PART 2: POSTERIOR TONSILLAR PILLAR, BIOPSY -
NO TUMOR SEEN.

PART 3: LYMPH NODES, RIGHT NECK LEVEL 1, BIOPSY -
A. TWO BENIGN LYMPH NODES (0/2).
B. SUBMANDIBULAR GLAND WITH NO SIGNIFICANT PATHOLOGIC CHANGE.

PART 4: SUPERFICIAL MANDIBLE MARGIN, BIOPSY -
NO TUMOR SEEN.

PART 5: RIGHT TONSILLAR--RETROMOLAR TRIGONE REGION, COMPOSITE RESECTION -
A. INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, 2.1 CM, EXTENSIVELY INVOLVING MANDIBLE.
B. NO ANGIOLYMPHATIC INVASION SEEN.
C. NO PERINEURAL INVASION SEEN.
D. FOCI OF INVASIVE SQUAMOUS CELL CARCINOMA INVOLVING ANTERIOR MANDIBULAR BONE MARGIN AND LATERAL SOFT TISSUE MARGIN.
E. SEVERE DYSPLASIA PRESENT AT ANTERIOR SOFT TISSUE AND MEDIAL SOFT TISSUE MARGINS.
F. PATHOLOGIC STAGE: pT4 N0 MX.

PART 6: RIGHT ALVEOLAR NERVE, BIOPSY -
NO TUMOR SEEN.

PART 7: RIGHT RETROMOLAR TRIGONE, BIOPSY -
NO TUMOR SEEN.

PART 8: ANTERIOR LABIAL MARGIN, BIOPSY -
NO TUMOR SEEN.

PART 9: LYMPH NODES, RIGHT NECK LEVELS 2, 3, AND 4, DISSECTION -
TWENTY-FOUR BENIGN LYMPH NODES (0/24).

PART 10: BONE MARROW MANDIBLE, RIGHT, BIOPSY -

[page 2 of 6]
[REDACTED]

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in a total of 10 parts.

Part 1 received fresh with the patient's name, initials [REDACTED], labeled "soft palate margin" and consists of a 0.8 x 0.6 x 0.5 cm of pink-hemorrhagic, soft tissue, entirely submitted following intraoperative consult labeled 1FS.

Part 2 received fresh with the patient's name, initials [REDACTED], labeled "posterior tonsillar pillar" consists of two irregular portions of pink-hemorrhagic, soft tissue, 1.0 x 0.5 x 0.5 cm and 0.7 x 0.4 x 0.4 cm. The soft tissue is entirely submitted following intraoperative consult labeled 2AFS.

Part 3 received unfixed with the patient's name, initials [REDACTED], labeled "right neck level I" consists of a 4.0 x 2.5 x 1.5 cm, 9.0-g light tan submandibular gland, with an attached 3.0 x 3.0 x 0.7 cm of pink and hemorrhagic fat and soft tissue. The gland on cross-section is grossly unremarkable. A representative section is submitted labeled 3A. Two lymph nodes dissected from the attached fat are entirely submitted along with remaining adipose tissue labeled 3B and 3C.

Part 4 received fresh with the patient's name, initials [REDACTED], labeled "superficial mandible margin" and consists of a 2.1 x 0.9 x 0.6 cm of pink and hemorrhagic soft tissue, entirely submitted following intraoperative consult labeled 4AFS.

Part 5 received fresh with the patient's name, initials [REDACTED], labeled "right composite resection" consists of a right composite resection with overall dimensions 8.0 x 5.5 x 4.4 cm. The mandible, 6.0 x 4.0 x 1.0 cm has hemorrhagic erosion of the cortical bone at the lateral ramus. The attached soft tissue consists of buccal mucosa, retromolar trigone and floor of mouth measuring 7.0 x 2.0 x 1.0 cm, with an irregular, tumor within the posterior oral region measuring 2.1 x 1.7 x 1.0 cm. The lesion comes to within 1.0 cm of the anterior soft tissue margin, 1.0 cm of the posterior soft tissue margin, 0.6 cm of the lateral soft tissue margin 0.7 cm of the medial soft tissue resection margin and 0.5 cm of the deep margin of resection.

A coronal section exposes tumor eroding the mandibular cortical bone at the medial aspect, possibly extending to the lateral cortical surface. The bone resection margins are grossly free of tumor.

Digital images are taken. Representative tumor and normal tissue is submitted for [REDACTED] banking.

Ink code:

Blue- lateral

Black- medial

Green- anterior

Yellow- posterior

Orange- deep

The following sections are submitted:

5A. anterior mandibular resection shave margin, following complex decalcification

5B. posterior mandibular shave margin, following complex decalcification

5C. anterior soft tissue shave margin

[page 3 of 6]
Pathology Report

- 5D. posterior soft tissue shave margin
5E. lateral soft tissue shave margin
5F. medial soft tissue shave margin and salivary gland
5G. deep soft tissue
5H. – J. additional sections of lesion with relation to tonsil and deep aspects
5K. – L. tumor extending into mandible, following complex decalcification

Part 6 received fresh with the patient's name, initials [REDACTED], labeled "right alveolar nerve" consists of a 0.9 x 0.6 x 0.4 cm of pink, soft tissue, entirely submitted following intraoperative consult labeled 6AFS.

Part 7 received fresh with the patient's name, initials [REDACTED] labeled "right retromolar trigone" consists of a 1.4 x 0.4 x 0.4 cm resection of pink hemorrhagic, soft tissue, entirely submitted following intraoperative consult labeled 7AFS.

Part 8 received fresh with the patient's name, initials [REDACTED] labeled "anterior labial margin" consists of a 1.5 x 0.4 x 0.4 cm of pink and hemorrhagic, soft tissue, entirely submitted following intraoperative consult labeled 8AFS.

Part 9 received unfixed with the patient's name, initials [REDACTED] labeled "right neck level 2, 3, 4 (stitch on two) consists of 3 pieces of yellow and hemorrhagic fat and soft tissue ranging from 3.0 x 1.0 x 0.5 cm to 6.0 x 4.0 x 1.5 cm. The largest portion of tissue has an attached black silk suture. Lymph nodes dissected from the larger portion are submitted as zone II lymph nodes in cassettes 9A through 9E. Lymph nodes dissected from the remaining tissue are also entirely submitted labeled 9F.

Part 10 received fresh with the patient's name, initials [REDACTED] labeled "bone marrow mandible right" consists of a 0.4 x 0.2 x 0.2 cm of dark red, soft to friable tissue, entirely submitted following intraoperative consult labeled 10AFS.

INTRAOPERATIVE CONSULTATION:

- 1FS: SOFT PALATE, MARGIN, BIOPSY (frozen section)-
A. BENIGN
B. NO TUMOR SEEN [REDACTED]
- 2FS: POSTERIOR TONSILLAR PILLAR, BIOPSY (frozen section)-
A. BENIGN
B. NO TUMOR SEEN [REDACTED]
- 4FS: SUPERFICIAL MANDIBLE MARGIN, BIOPSY (frozen section)-
A. BENIGN
B. NO TUMOR SEEN [REDACTED]
- 6FS: RIGHT ALVEOLAR NERVE, BIOPSY (frozen section)-
A. BENIGN
B. NO TUMOR SEEN [REDACTED]
- 7FS: RIGHT RETROMOLAR TRIGONE, BIOPSY (frozen section)-
A. BENIGN
B. NO TUMOR SEEN [REDACTED]
- 8FS: ANTERIOR LABIAL MARGIN, BIOPSY (frozen section)-
A. BENIGN
B. NO TUMOR SEEN [REDACTED]
- 10FS: BONE MARROW MANDIBLE, RIGHT, BIOPSY (frozen section)-

[page 4 of 6]
- A. BENIGN
B. BONE FRAGMENTS, NO TUMOR SEEN

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED], Department of Pathology, as required by the CLIA regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED].

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE:

Resection: Composite resection

TUMOR SITE:

Other: Right retromolar trigone

TUMOR SIZE:

Greatest dimension: 2.1 cm

HISTOLOGIC TYPE:

Squamous cell carcinoma, conventional

HISTOLOGIC GRADE:

G2

PATHOLOGIC STAGING (pTNM):

pT4

pN0

Number of regional lymph nodes examined: 26

Number of regional lymph nodes involved: 0

MARGINS:

pMX

Margin(s) involved by tumor

Location(s): anterior mandible margin and lateral soft tissue margin

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Absent

PERINEURAL INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Epithelial dysplasia

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Soft palate margin

Taken: [REDACTED]

Stain/chn

Block

H&E x 1

AFS

Part 2: Posterior tonsillar pillar

Taken: [REDACTED]

Stain/chn

Block

H&E x 1

AFS

Part 3: Right neck level 4

Taken: [REDACTED]

Stain/chn

Block

[page 5 of 6]
Pathology Report

H&E x 1 A
H&E x 1 B
H&E x 1 C

Part 4: Superior mandible margin

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS

Part 5: Right composite mandible resection

Taken: [REDACTED]
Stain/cnt Block
DC x 1 A
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K
H&E x 1 L
IMSU x 7 (none)

Part 6: Right alveolar nerve

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS

Part 7: Right reframolar trigone

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS
H&E x 1 AFS

Part 8: Anterior labial margin

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS

Part 9: Right neck levels 2, 3, 4

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F

[page 6 of 6]
Pathology Report

Part 10: Bone marrow right mandible

Taken: [redacted]

Stain/cn: [redacted]

H&E x 1 AFS

ICD-9 Diagnosis Codes: 000

Source: NCI Genomic Data Commons file 282c488e-0847-4b02-9c90-96689a71e2d9 (TCGA-CN-4740.0C28AE48-C42E-49FF-832B-021FA529B4B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).